Somatic mutation profile of tumor specimen TCGA-F6-A8O3-01A (aliquot TCGA-F6-A8O3-01A-11D-A36O-08) from TCGA case TCGA-F6-A8O3, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 34.4 years (12,578 days).
Specimen TCGA-F6-A8O3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dbe3633-b1f7-4e1b-81bd-678b29561278.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F6-A8O3-10A (Blood Derived Normal), aliquot TCGA-F6-A8O3-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ff9bb81-80c1-463e-97af-c61bce379b5d

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 15, Silent 5, Splice Site 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/89 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATM | c.2117C>A p.S706* | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as COSV99590083; called by muse, mutect2, varscan2
- CEMIP2 | c.2273G>A p.R758Q | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as rs140238648; called by muse, mutect2, varscan2
- CNGB1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.005); catalogued as rs368957667, COSV99202890; called by muse, varscan2
- CPAMD8 | c.2211+1G>A p.X737_splice (on ENST00000651564; = p.X690_splice on NM_015692.5) | Splice Site (SNP) | VAF 8/15 reads (53%) | catalogued as rs374939930; called by muse, mutect2, varscan2
- CYP2C18 | c.961+2T>C p.X321_splice | Splice Site (SNP) | VAF 36/83 reads (43%) | catalogued as rs947420618, COSV99608616; called by muse, mutect2, varscan2
- DAB2 | c.61A>G p.K21E | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100298075; called by muse, mutect2, varscan2
- FOXI1 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886060398, COSV100089439; called by muse, mutect2
- PDGFD | c.335A>G p.D112G | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100159531; called by muse, mutect2, varscan2
- POT1 | c.482A>T p.Y161F | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV100714081; called by muse, mutect2
- POT1 | c.480G>T p.Q160H | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as COSV100714082; called by muse, mutect2
- RIPK4 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.043); catalogued as rs552648714, COSV60192919; called by muse, mutect2, varscan2
- SLC2A14 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as rs761502383, COSV61585446; called by muse, mutect2, varscan2
- SLITRK3 | c.2114G>A p.C705Y | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.979); catalogued as COSV99579449, COSV99579715; called by muse, mutect2, varscan2
- SMARCA4 | c.2441C>A p.T814K | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60792950, COSV60795041; called by muse, mutect2, varscan2
- SNX27 | c.1118A>G p.N373S | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs149636067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSKU | c.598C>G p.P200A | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100290122; called by muse, mutect2, varscan2
- NIPBL | c.6540_6546del p.K2182Qfs*13 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- B4GALT3 | c.669G>A p.K223= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100157789; called by muse, mutect2, varscan2
- CPEB1 | c.1509T>C p.A503= (on ENST00000617958; = p.A438= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as COSV99917775; called by muse, mutect2, varscan2
- KIAA1217 | c.546A>G p.R182= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs1053956034, COSV100908046; called by muse, mutect2, varscan2
- KRT33B | c.810G>A p.A270= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as rs760179357, COSV52442538; called by muse, mutect2, varscan2
- KRT85 | c.354C>T p.C118= | Silent (SNP) | VAF 60/185 reads (32%) | catalogued as COSV99225503; called by muse, mutect2, varscan2
